Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28G, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28G-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Ascending Colon			
Date of Cancer Sample Procurement:				
Histology:	Adenocarcinoma			
Description of other histology:				
Grade:	Well Differentiated			
Mucinous:	☐ No	☐ Yes	☒ Yes (Focal)	☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown	
Host Response:	None			
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown	
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown	
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive	☐ Unknown
Inflammatory Bowel Disease	☐ No	☐ Yes	☒ Unknown	
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown	
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown	
Number of Slides	1			
Garland Necrosis present:	☒ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
TIL Cells / HPF	3.4			
Pathologist Comment:				

ICD-0-3

Path-

Site: ascending colon C18.2

lw 5/3/11

CQCF: adenocarcinoma, NOS 8140/3

lw 5/3/11

Source: NCI Genomic Data Commons file 2e8ec192-1c33-43a0-89eb-f52c925ef5f7 (TCGA-DM-A28G.1CA5DFB2-8059-4D71-862C-638393435618.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).